CCDI case PBCKSZ — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/b75bb189-79dd-4be6-8bcd-b5cb01e0ae87

Demographics
Sex at birth: male; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Medulloblastoma, NOS: ICD-O-3 morphology code: 9470/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 8.8 years (3,225 days).

Biospecimens (3 samples)
- Sample 0DU7ZW: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DU80C: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DU81A: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
